CGCI case HTMCP-03-06-02396 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/81b9e35b-f290-419a-9286-e475065b09e4

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Dead; Days to death: 87 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Squamous cell carcinoma, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 47.4 years (17,324 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC clinical T: T3a; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IIIA; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 87 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 26 days; Days to treatment end: 33 days; Treatment dose: 18; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Treatment anatomic sites: Cervix.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 87 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day -3,871.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day -3,871: Comorbidities: HIV/AIDS.
- Day -3,871: Risk factors: HIV/AIDS.
- Day 0: Pregnancy outcome: Miscarriage.
- Day 0: Weight: 43.6 kg; Height: 142.5 cm; BMI: 21.5; CD4 count: 428; Haart treatment indicator: Yes; HIV viral load: 70; Hormonal contraceptive use: Former User; Hysterectomy type: Not Performed; Menopause status: Perimenopausal; Pregnant at diagnosis: No.
- Day 0: Nadir CD4 count: 32.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02396-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02396-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Peri (6-12 months since last menstrual period); Weight kg at diagnosis: 43.6 kg; History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 08; Pregnancies count miscarriage: 01; Pregnancies count induced abortion: 00; Pregnancies count ectopic: 00; Pregnancies count stillbirth: 00; Total pregnancy count: 09; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lymph nodes examined: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 2006; Nadir cd4 counts: 0032; HIV rna load at diagnosis: 000070; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; Cd4 counts at diagnosis: 0428.
- Follow-up form: Tumor status: With tumor; Cause of death: Cervical Cancer; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form, Treatment, Radiation therapy info: Brachytherapy type: HDR.
- Follow-up form, Treatment, Concurrent prescription treatment info: Chemo concurrent reason not given: Not done per treating physicians discretion.
- Treatments, Treatment: Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 18.
